Surgical pathology report (de-identified scan), TCGA case TCGA-ER-A42K, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Pittsburgh, specimen TCGA-ER-A42K-06A (Metastatic).

FINAL DIAGNOSIS:

1. SKIN, LEFT DORSAL HAND, EXCISION:

- RESIDUAL MALIGNANT MELANOMA IS OBSERVED.
- THE NEOPLASM IS COMPLETELY EXCISED.
- CICATRIX AND CHANGES CONSISTENT WITH PREVIOUS BIOPSY SITE ARE SEEN.

2. SOFT TISSUE, CONTENTS OF LEFT AXILLA, LYMPH NODE DISSECTION:

- FIVE OF FIFTEEN (5/15) LYMPH NODES POSITIVE FOR METASTATIC MELANOMA, LARGEST FOCUS IS 6.8 CM IN GREATEST DIMENSION (measured grossly - see gross description) (see comment).
- EXTRACAPSULAR SPREAD IS IDENTIFIED.

3. SOFT TISSUE, TRUE DEEP MARGIN LEFT HAND, EXCISION: NO RESIDUAL MELANOCYTIC NEOPLASM IS OBSERVED.

COMMENT:

- This is confirmed by interpretation of multiple deeper levels and immunoperoxidase stains (S100 and tyrosinase).

MICROSCOPIC:

The microscopic findings substantiate the diagnosis.

The following statement applies to all immunohistochemistry, insitu hybridization (ISH & FISH), molecular anatomic pathology, and immunofluorescence testing:

The testing was developed and its performance characteristics determined by the required by the CLIA '88 regulations. The testing has not been cleared or approved for the specific use by the U.S. Food and Drug Administration, but the FDA has determined such approval is not necessary for clinical use. Tissue fixation ranges from a minimum of 2 to a maximum of 84 hours.

This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 ("CLIA") as qualified to perform high-complexity clinical testing. Pursuant to the requirements of CLIA, ASR's used in this laboratory have been established and verified for accuracy and precision. Additional information about this type of test is available upon request.

PATIENT HISTORY:

Preop Diagnosis: metastatic melanoma/malignant neoplasm, left hand
Postop Diagnosis: metastatic melanoma/malignant neoplasm, left hand
Surgical Procedure: DISSECTION AXILLARY NODES
Surgical Procedure: DEBRIDEMENT WOUND SPLIT THICKNESS SKIN GRAFT

ICD-O-3

melanoma NOS

8720/3

Site: lymph node, axilla

9-1-12

RD

07.3

8/2/12

Source: NCI Genomic Data Commons file 602de4ef-0a10-41c1-9391-8d96be11ba1b (TCGA-ER-A42K.E9A8E763-DC34-4284-9CCE-455578172A5A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).